Somatic mutation profile of tumor specimen 7c2aeacf-a30d-4104-b60a-7545ee (aliquot 7c2aeacf-a30d-4104-b60a-7545ee_D6_1) from CPTAC case 17OV010, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary.
Specimen 7c2aeacf-a30d-4104-b60a-7545ee: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29223b44-52f6-4820-8438-aa00929e99e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a1941d5e-aa5a-46d1-b995-3d4278 (Blood Derived Normal), aliquot a1941d5e-aa5a-46d1-b995-3d4278_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d60b130d-ef39-49d5-975e-50943d5a2efe

The open-access MAF lists 178 somatic variants for this specimen: 111 protein-altering or splice-affecting, 42 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 42, Intron 10, 5'UTR 7, Nonsense Mutation 7, Splice Site 5, RNA 4, 3'UTR 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRG2 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 95/236 reads (40%) | catalogued as rs796052504, CM108346, COSV62722263; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GCDH | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 151/356 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs576948027, CD120083; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLA | c.1067G>C p.R356P | Missense Mutation (SNP) | VAF 68/83 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs869312163, CM096038, CM160462; ClinVar: drug response / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 146/321 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM086852, CM092998, COSV61071862, COSV61073592; called by muse, mutect2
- TP53 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 163/379 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1057520006, COSV52662012, COSV52709979, COSV52761348, COSV53124293; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 96/254 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs782249244, COSV100984233; called by muse, mutect2, varscan2
- ARFGEF3 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.328); catalogued as COSV52449768; called by muse, mutect2, varscan2
- ATP11A | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs551993113, COSV52105821; called by muse, mutect2, varscan2
- BBS12 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1351171130, COSV58562059, COSV58562265; called by muse, mutect2, varscan2
- BCL2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1228330940, COSV104414320, COSV61397138; called by muse, mutect2, varscan2
- CARD11 | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 91/180 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV67797547; called by muse, mutect2, varscan2
- CERS6 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1462178134, COSV59834452; called by muse, varscan2
- CIDEA | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs774575110, COSV57597098; called by muse, mutect2, varscan2
- CREBBP | c.4301T>C p.L1434P | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52125476, COSV52127962, COSV52138863; called by muse, mutect2, varscan2
- CYP4F2 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751427624, COSV99686261; called by muse, mutect2, varscan2
- DLC1 | c.1774T>C p.S592P (on ENST00000276297 / NM_001348081.2; = p.S155P on NM_006094.5) | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as rs1361298062; called by muse, mutect2, varscan2
- DLK1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs781097687; called by muse, mutect2, varscan2
- FGFR2 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 129/461 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs148672240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLRA2 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 278/338 reads (82%) | catalogued as COSV54337159; called by mutect2, varscan2
- GOLGA6L2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.329); catalogued as rs779539911; called by muse, mutect2, varscan2
- IGLC3 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 439/517 reads (85%) | PolyPhen possibly damaging (0.682); catalogued as rs1401816566; called by mutect2, varscan2
- ING3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 60/139 reads (43%) | catalogued as rs1419837407, COSV100253268; called by muse, mutect2, varscan2
- KIAA1109 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1235726317, COSV52661055, COSV99149397; called by muse, mutect2, varscan2
- LIMK2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs773495668, COSV59183212; called by muse, mutect2, varscan2
- LRRIQ1 | c.4160A>G p.N1387S | Missense Mutation (SNP) | VAF 129/238 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV67837955; called by muse, mutect2, varscan2
- MED13 | c.5830A>T p.M1944L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV101180902; called by muse, mutect2, varscan2
- MEF2C | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 72/167 reads (43%) | catalogued as COSV60929590; called by muse, varscan2
- MEIS2 | c.331G>A p.G111R (on ENST00000561208 / NM_170675.5; = p.G98R on NM_002399.3) | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV54938940; called by muse, mutect2, varscan2
- MTNR1A | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 168/363 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs372168234; called by muse, mutect2, varscan2
- MUC12 | c.2179C>T p.P727S (on ENST00000379442; = p.P584S on NM_001164462.1) | Missense Mutation (SNP) | VAF 138/494 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.65); catalogued as rs557187334; called by muse, mutect2, varscan2
- NCAM2 | c.2487A>C p.Q829H | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99521696; called by muse, mutect2, varscan2
- NEK3 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 88/116 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs760462632; called by muse, mutect2, varscan2
- PAGE3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs372486004, COSV100891987, COSV100892009; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1280T>A p.L427* (on ENST00000259318 / NM_001136562.3; = p.L658* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 86/207 reads (42%) | catalogued as COSV52178342; called by muse, mutect2, varscan2
- PRB2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs373878795, COSV66984419; called by muse, mutect2, varscan2
- PRDM13 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV65029191; called by muse, mutect2, varscan2
- PRKD1 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs778620548; called by muse, mutect2, varscan2
- PRKN | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 193/459 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as rs748892763, COSV58262516; called by muse, mutect2, varscan2
- PSAPL1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as rs1442850443; called by muse, mutect2, varscan2
- PSMD1 | c.1426G>C p.G476R | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58077802; called by muse, mutect2, varscan2
- RAB3B | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs766991334, COSV100862521, COSV65434046; called by muse, mutect2, varscan2
- RABEP1 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52588374; called by muse, mutect2, varscan2
- RALYL | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 197/247 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV72820118; called by muse, mutect2, varscan2
- SCAF1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100862353; called by muse, mutect2, varscan2
- SEMA3A | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149953379; called by muse, mutect2, varscan2
- SEMA3G | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776883040, COSV51595255; called by muse, mutect2, varscan2
- SGMS2 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV62989325; called by muse, mutect2, varscan2
- SH3RF2 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373327542; called by muse, mutect2, varscan2
- SHPRH | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.619); catalogued as rs777055416, COSV51606838; called by muse, mutect2, varscan2
- SLC22A3 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1269442475; called by muse, mutect2
- SMOC1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 176/462 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs760870751, COSV62760110; called by muse, mutect2, varscan2
- STAB2 | c.2278G>C p.G760R | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761459390, COSV101185700; called by muse, mutect2, varscan2
- SYNE1 | c.3889G>A p.A1297T (on ENST00000367255 / NM_182961.4; = p.A1304T on NM_033071.3) | Missense Mutation (SNP) | VAF 175/390 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs781769990, COSV99549415; called by muse, mutect2, varscan2
- TAF1L | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs764175922, COSV54267502, COSV99644025; called by muse, mutect2, varscan2
- THOC2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV99833316; called by muse, mutect2, varscan2
- TRIM67 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs767206410, COSV100792148; called by muse, mutect2, varscan2
- UBR3 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749828158, COSV55847839; called by muse, mutect2, varscan2
- ZMYM1 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs777278071, COSV63252700; called by muse, mutect2, varscan2
- ZNF676 | c.718A>C p.K240Q (on ENST00000650058; = p.K208Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.038); catalogued as rs746645272; called by muse, varscan2
- ZNF676 | c.485G>A p.R162K (on ENST00000650058; = p.R130K on NM_001001411.3) | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101236309, COSV68095125; called by muse, varscan2
- AUP1 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- C12orf71 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2CD6 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- C5 | c.1716_1716+28delinsCAAATTATAAGTCAC p.X572_splice | Splice Site (DEL) | VAF 62/246 reads (25%) | called by pindel, varscan2*
- CCR6 | c.1018A>T p.K340* | Nonsense Mutation (SNP) | VAF 70/172 reads (41%) | called by muse, mutect2, varscan2
- CDC27 | c.1933T>A p.Y645N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST9 | c.911T>A p.V304E | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CLNK | c.650-2A>G p.X217_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- CYP3A5 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DCHS1 | c.4037G>A p.R1346Q | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX27 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- DNAH14 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- DNAH8 | c.9152A>T p.N3051I | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK1 | c.4299G>T p.E1433D | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ESPNL | c.2719G>C p.E907Q | Missense Mutation (SNP) | VAF 137/318 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLT3LG | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FREM3 | c.1328T>G p.L443R | Missense Mutation (SNP) | VAF 121/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPLD1 | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- HERC5 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- LRRC15 | c.1678G>C p.G560R | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- MATR3 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8D1 | c.242T>G p.M81R | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- OR8J3 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PADI3 | c.1083C>G p.H361Q | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PCDHA13 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 164/372 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PEMT | c.79A>C p.N27H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PER2 | c.2371dup p.T791Nfs*19 | Frame Shift Ins (INS) | VAF 106/274 reads (39%) | called by mutect2, varscan2
- PPIC | c.634T>A p.W212R | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRPH | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- RAB40C | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RBM25 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RFC1 | c.2439+1G>A p.X813_splice (on ENST00000381897 / NM_001363496.2; = p.X812_splice on NM_002913.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- SEC24B | c.2258C>G p.P753R | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3GL3 | c.54T>G p.S18R | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SI | c.5241A>T p.L1747F | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC1A3 | c.298A>T p.I100F | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLCO3A1 | c.45C>A p.S15R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.254); called by muse, mutect2
- SMAP1 | c.550C>T p.P184S (on ENST00000370455 / NM_001044305.3; = p.P157S on NM_021940.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOX18 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYCP2 | c.1033+2T>A p.X345_splice | Splice Site (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- TNKS2 | c.1259T>G p.V420G | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TSPYL4 | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 174/368 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TTN | c.25046T>C p.L8349P (on ENST00000591111; = p.L7422P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/140 reads (41%) | PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UPP1 | c.162+1G>A p.X54_splice | Splice Site (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- USP48 | c.1407C>G p.H469Q | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- WWP1 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF274 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF548 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZNF768 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRB3 | c.1245G>A p.T415= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs146799555; called by muse, mutect2, varscan2
- AL645922.1 | c.1395C>T p.V465= | Silent (SNP) | VAF 191/433 reads (44%) | catalogued as rs772507515; called by muse, mutect2, varscan2
- ARL10 | c.294G>A p.S98= | Silent (SNP) | VAF 106/275 reads (39%) | catalogued as rs779312966, COSV53798805; called by muse, mutect2, varscan2
- BBS9 | c.1380C>T p.Y460= | Silent (SNP) | VAF 127/291 reads (44%) | catalogued as rs376024532; called by muse, mutect2, varscan2
- BCR | c.73C>T p.L25= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV59934034, COSV59934164; called by muse, mutect2, varscan2
- CCDC166 | c.1293G>C p.A431= | Silent (SNP) | VAF 91/103 reads (88%) | catalogued as rs919111171; called by muse, mutect2, varscan2
- CEACAM19 | c.822G>A p.A274= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs376767671; called by muse, mutect2, varscan2
- CRPPA | c.1152C>A p.P384= (on ENST00000407010 / NM_001368197.1; = p.P334= on NM_001101417.4) | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV67904605; called by muse, mutect2, varscan2
- FANCD2 | c.2646T>C p.S882= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- FNDC3A | c.1332G>C p.S444= (on ENST00000492622 / NM_001079673.2; = p.S388= on NM_014923.5) | Silent (SNP) | VAF 60/74 reads (81%) | catalogued as COSV101256844; called by muse, mutect2, varscan2
- FRRS1L | c.150G>C p.T50= | Silent (SNP) | VAF 12/23 reads (52%) | called by muse, varscan2
- GPR148 | c.384C>T p.V128= | Silent (SNP) | VAF 13/403 reads (3%) | called by muse, mutect2
- HOMER2 | c.33G>A p.A11= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs201522712, COSV58484566; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LYSMD4 | c.678G>T p.L226= (on ENST00000409796 / NM_001284417.2; = p.L227= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 236/521 reads (45%) | called by muse, mutect2, varscan2
- MAP2K1 | c.390T>C p.Y130= | Silent (SNP) | VAF 144/320 reads (45%) | called by muse, mutect2
- MTNR1A | c.708T>C p.N236= | Silent (SNP) | VAF 108/276 reads (39%) | called by muse, mutect2, varscan2
- MYO7A | c.4542A>G p.P1514= | Silent (SNP) | VAF 83/179 reads (46%) | called by muse, mutect2, varscan2
- NAT1 | c.528T>C p.L176= | Silent (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- NISCH | c.244A>C p.R82= | Silent (SNP) | VAF 36/83 reads (43%) | called by muse, varscan2
- NLRP12 | c.1638C>T p.T546= | Silent (SNP) | VAF 136/275 reads (49%) | catalogued as rs762831332, COSV100145075, COSV60743457; called by muse, mutect2, varscan2
- OVCH2 | c.765G>C p.L255= | Silent (SNP) | VAF 69/178 reads (39%) | called by muse, mutect2, varscan2
- PCED1B | c.168C>T p.F56= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV71395017; called by muse, mutect2, varscan2
- PEG3 | c.4587C>T p.S1529= | Silent (SNP) | VAF 173/389 reads (44%) | called by muse, mutect2, varscan2
- PIK3R5 | c.2089C>T p.L697= | Silent (SNP) | VAF 97/199 reads (49%) | called by muse, mutect2, varscan2
- PLCL2 | c.1449A>T p.V483= (on ENST00000615277 / NM_001144382.2; = p.V357= on NM_015184.5) | Silent (SNP) | VAF 113/292 reads (39%) | called by muse, mutect2, varscan2
- PLEC | c.12696G>A p.T4232= (on ENST00000322810 / NM_201380.4; = p.T4122= on NM_000445.5) | Silent (SNP) | VAF 476/557 reads (85%) | catalogued as rs200145450, COSV59639795; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLR3H | c.249G>A p.E83= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs749222450; called by muse, mutect2, varscan2
- POTEE | c.1650C>T p.V550= | Silent (SNP) | VAF 76/271 reads (28%) | catalogued as rs779703299, COSV58227508, COSV58230035; called by muse, mutect2, varscan2
- PPP6R2 | c.1203C>T p.H401= | Silent (SNP) | VAF 102/219 reads (47%) | catalogued as rs200416894; called by muse, mutect2, varscan2
- PRAME | c.1413G>T p.L471= | Silent (SNP) | VAF 88/217 reads (41%) | called by muse, mutect2, varscan2
- SHROOM1 | c.2052G>C p.A684= | Silent (SNP) | VAF 89/217 reads (41%) | called by muse, mutect2, varscan2
- SLC17A2 | c.717G>C p.P239= | Silent (SNP) | VAF 86/202 reads (43%) | catalogued as rs370105405; called by muse, mutect2, varscan2
- SP5 | c.672C>T p.A224= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- TAB2 | c.582T>C p.S194= | Silent (SNP) | VAF 238/550 reads (43%) | called by muse, mutect2, varscan2
- TBKBP1 | c.414C>T p.C138= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as rs758608914; called by muse, mutect2, varscan2
- TMPRSS11D | c.1086C>T p.D362= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as rs1428314205; called by muse, mutect2, varscan2
- TRANK1 | c.1174T>C p.L392= | Silent (SNP) | VAF 110/236 reads (47%) | catalogued as rs939684950; called by mutect2, varscan2
- TRERF1 | c.3543C>T p.D1181= | Silent (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- TSHR | c.1341C>T p.N447= | Silent (SNP) | VAF 218/487 reads (45%) | catalogued as rs777698828, COSV53325750, COSV53328811; called by muse, mutect2, varscan2
- TSHZ2 | c.1293G>A p.S431= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as rs749447914, COSV61589070; called by muse, mutect2, varscan2
- TTBK1 | c.1176C>T p.P392= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs754329015, COSV52493634; called by muse, mutect2, varscan2
- ZNF676 | c.273A>T p.I91= (on ENST00000650058; = p.I59= on NM_001001411.3) | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV68095341; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826532 G>A | 3'Flank (SNP) | VAF 113/137 reads (82%) | catalogued as rs377563423; called by muse, mutect2, varscan2
- ARHGEF18 | c.-109T>C | 5'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2870-114C>T | Intron (SNP) | VAF 89/202 reads (44%) | catalogued as rs1295492712; called by muse, mutect2, varscan2
- CCER1 | chr12:90947693 G>A | 3'Flank (SNP) | VAF 44/149 reads (30%) | catalogued as rs932522851; called by muse, mutect2, varscan2
- CDCA7 | c.-23C>A | 5'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- DIP2C | c.85+27450_85+27451insA | Intron (INS) | VAF 36/122 reads (30%) | called by mutect2, pindel*, varscan2*
- EDIL3 | c.-15C>G | 5'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- FAM76B | c.88-362G>C | Intron (SNP) | VAF 63/143 reads (44%) | called by muse, mutect2, varscan2
- FAS | c.*23_*24dup | 3'UTR (INS) | VAF 71/125 reads (57%) | catalogued as COSV58239495; called by mutect2, pindel, varscan2
- HERC2P3 | n.1644G>A | RNA (SNP) | VAF 159/399 reads (40%) | called by muse, mutect2, varscan2
- HTR3B | c.-12A>G | 5'UTR (SNP) | VAF 70/149 reads (47%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.-9T>G | 5'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- IPO8 | c.640-487C>T | Intron (SNP) | VAF 123/217 reads (57%) | catalogued as rs766759097; called by muse, mutect2, varscan2
- LINC02145 | n.385G>A | RNA (SNP) | VAF 81/163 reads (50%) | catalogued as rs775408559; called by muse, mutect2, varscan2
- LINC02870 | n.308C>A | RNA (SNP) | VAF 127/415 reads (31%) | called by muse, mutect2, varscan2
- NECTIN3 | c.160+2050G>A | Intron (SNP) | VAF 77/183 reads (42%) | called by muse, mutect2, varscan2
- P3H3 | c.1265+22G>A | Intron (SNP) | VAF 81/292 reads (28%) | catalogued as rs781821847; called by muse, mutect2, varscan2
- PKD1L2 | n.126C>T | RNA (SNP) | VAF 37/87 reads (43%) | catalogued as rs1489734186; called by muse, mutect2, varscan2
- PLCD1 | c.35-4235T>C | Intron (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- PNISR | c.1102+54A>T | Intron (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- POLRMT | c.-10G>A | 5'UTR (SNP) | VAF 24/32 reads (75%) | called by muse, mutect2, varscan2
- PPP2R5C | c.93+2188A>G | Intron (SNP) | VAF 51/125 reads (41%) | catalogued as rs911971159; called by muse, mutect2, varscan2
- RAP1B | c.468+15A>T | Intron (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- UQCRB | c.*3119C>T | 3'UTR (SNP) | VAF 200/232 reads (86%) | catalogued as rs776728902; called by muse, mutect2, varscan2
- ZNRF2 | c.-323C>T | 5'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
